FM case AD11239 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/260e13bf-5b38-403d-ac3a-e9f96d6d6b75

Female, 54.5 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
